Gene-level copy-number profile of tumor specimen C3N-03428-01 (profiled together with C3N-03428-02) from CPTAC case C3N-03428, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 63.4 years (23,159 days).
Specimen C3N-03428-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8e4e7acd-8977-40b3-a366-6db61b273ba8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03428-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/8d9393e1-3b56-46d6-b402-31e7c62b8b1c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 104; copy number 1: 3,228; copy number 2: 55,178; copy number 3: 319; copy number 4: 72; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 104 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,978,459–22,552,156, 104 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:22,684,958–22,966,063, 4 genes, copy number 5 (within-gene range 4–5): AL158175.1, KRT18P3, CYB5AP4, AL353132.1.

Autosomal genes at a single copy (total copy number 1): 372. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
